Somatic mutation profile of tumor specimen TCGA-79-5596-01A (aliquot TCGA-79-5596-01A-31D-1945-08) from TCGA case TCGA-79-5596, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA.
Specimen TCGA-79-5596-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 757bdd14-74f3-474e-bc56-37f6dba0fa05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-79-5596-10A (Blood Derived Normal), aliquot TCGA-79-5596-10A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbf1e1c5-e735-431a-a92d-788907a54b5a

The open-access MAF lists 211 somatic variants for this specimen: 150 protein-altering or splice-affecting, 53 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 53, Nonsense Mutation 14, Frame Shift Del 6, Splice Site 6, Intron 3, RNA 2, Frame Shift Ins 2, 3'Flank 1, 3'UTR 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 30/42 reads (71%) | hotspot (GDC flag); catalogued as CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; called by muse, mutect2, varscan2
- ABHD2 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.396); catalogued as COSV100756491; called by muse, mutect2, varscan2
- ACSM1 | c.863C>G p.T288R | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54638535, COSV99533490; called by muse, mutect2, varscan2
- ACTN4 | c.2127G>T p.Q709H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99400821; called by muse, mutect2, varscan2
- ADAM12 | c.977C>G p.T326R | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100901660, COSV100901733; called by muse, varscan2
- ADCK1 | c.1201A>G p.T401A | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs778693800, COSV99452781; called by muse, mutect2, varscan2
- ADD2 | c.1013G>T p.R338L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV100036599; called by muse, mutect2, varscan2
- ADGRB3 | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV100999516, COSV65418202; called by muse, mutect2, varscan2
- AGFG1 | c.1210G>T p.V404F | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.157); catalogued as COSV100029218; called by muse, mutect2, varscan2
- AMER3 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | catalogued as rs764804784, COSV58471342; called by muse, varscan2
- ANKRD30A | c.1915C>A p.P639T (on ENST00000611781; = p.P583T on NM_052997.2) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs759205712, COSV100654524; called by muse, mutect2, varscan2
- APBB2 | c.2057G>A p.W686* (on ENST00000295974 / NM_001166050.2; = p.W687* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 15/27 reads (56%) | catalogued as COSV55947757; called by muse, mutect2, varscan2
- APOA4 | c.454C>A p.Q152K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV100759400, COSV63360889; called by muse, mutect2, varscan2
- ARMC3 | c.2120G>T p.G707V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV99958975; called by muse, mutect2, varscan2
- ASPM | c.8252G>T p.G2751V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99661203; called by muse, mutect2, varscan2
- ATG2A | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs746013952, COSV65965826; called by muse, mutect2, varscan2
- ATP6V1H | c.1366G>T p.V456L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.38); catalogued as COSV100778871, COSV62218539; called by muse, mutect2, varscan2
- B3GLCT | c.460-2A>G p.X154_splice | Splice Site (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100587511; called by muse, mutect2, varscan2
- BCO2 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100730512; called by muse, mutect2, varscan2
- BMP4 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99817163; called by muse, mutect2, varscan2
- C8orf34 | c.620T>A p.V207E | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs535057811, COSV100448110; called by muse, mutect2, varscan2
- CDC5L | c.1696A>G p.T566A | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV101015235; called by muse, mutect2, varscan2
- CDH26 | c.1651T>G p.L551V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV99723084; called by muse, mutect2, varscan2
- CNNM1 | c.1257G>C p.Q419H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV100764002; called by muse, mutect2, varscan2
- COIL | c.133A>T p.I45F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99538422; called by muse, mutect2
- COL6A3 | c.7648C>T p.Q2550* | Nonsense Mutation (SNP) | VAF 77/158 reads (49%) | catalogued as COSV55085531; called by muse, mutect2, varscan2
- CSMD3 | c.8929T>G p.C2977G (on ENST00000297405 / NM_001363185.1; = p.C2808G on NM_052900.3) | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99849543; called by muse, mutect2, varscan2
- CSMD3 | c.2036G>T p.G679V (on ENST00000297405 / NM_001363185.1; = p.G575V on NM_052900.3) | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV52147264, COSV99849546; called by muse, mutect2, varscan2
- CSMD3 | c.515-2A>G p.X172_splice | Splice Site (SNP) | VAF 4/74 reads (5%) | catalogued as COSV99849547; called by muse, mutect2
- DCAF4 | c.441C>G p.H147Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100611187; called by muse, mutect2, varscan2
- DCDC1 | c.2758C>T p.P920S (on ENST00000597505 / NM_001367979.1; = p.P27S on NM_020869.3) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs543287068, COSV100337954, COSV100338846; called by muse, mutect2, varscan2
- DCLRE1C | c.115A>G p.M39V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100739998; called by muse, mutect2
- DNASE2B | c.803G>A p.W268* | Nonsense Mutation (SNP) | VAF 14/23 reads (61%) | catalogued as COSV101042149; called by muse, mutect2, varscan2
- DOCK11 | c.3868G>A p.V1290I | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs377585708, COSV99354883; called by muse, mutect2, varscan2
- DPP4 | c.1058G>T p.W353L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs946410578, COSV100859129; called by muse, mutect2, varscan2
- DUT | c.353G>C p.R118P (on ENST00000331200 / NM_001025248.2; = p.R30P on NM_001948.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV100485340; called by muse, mutect2, varscan2
- ELAVL4 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100836934, COSV63915352; called by muse, mutect2, varscan2
- ENPP1 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV62933854; called by muse, mutect2, varscan2
- ERC1 | c.3101G>A p.C1034Y (on ENST00000360905 / NM_178040.4; = p.C1006Y on NM_178039.4) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as COSV100706833; called by muse, mutect2, varscan2
- F13B | c.1636G>T p.G546C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803504; called by muse, mutect2, varscan2
- FAM126A | c.153+1G>A p.X51_splice | Splice Site (SNP) | VAF 8/33 reads (24%) | catalogued as COSV101300023; called by muse, mutect2, varscan2
- FBLN5 | c.253T>G p.S85A | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99970036; called by muse, mutect2, varscan2
- FCGR2B | c.181G>C p.V61L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99375422; called by muse, mutect2, varscan2
- FER1L6 | c.3967G>A p.G1323S | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs767605997, COSV67552769; called by muse, mutect2, varscan2
- FH | c.817G>C p.A273P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100845096, COSV63818612; called by muse, mutect2, varscan2
- FSHR | c.535A>T p.K179* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100438210; called by muse, mutect2, varscan2
- GLP2R | c.1431T>G p.C477W | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.501); catalogued as COSV99302547; called by muse, mutect2
- GLP2R | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV99302548; called by muse, mutect2
- GPC5 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs372530892, COSV65605013, COSV65615616; called by muse, mutect2, varscan2
- GRM8 | c.1601G>T p.C534F | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100286424; called by muse, mutect2, varscan2
- H3C11 | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.262); catalogued as COSV100137751, COSV58899594; called by muse, mutect2, varscan2
- HOXA4 | c.689T>A p.L230Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100415731; called by muse, mutect2, varscan2
- IFT88 | c.1427C>T p.A476V (on ENST00000319980 / NM_001318493.2; = p.A467V on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV100179950; called by muse, mutect2, varscan2
- IL7R | c.166A>C p.T56P | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as CX118705, COSV100286722, COSV57409589; called by muse, mutect2, varscan2
- IPO5 | c.2836+1G>A p.X946_splice | Splice Site (SNP) | VAF 15/34 reads (44%) | catalogued as COSV55161321, COSV99847710; called by muse, mutect2, varscan2
- ITLN1 | c.580T>C p.Y194H | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100406411; called by muse, mutect2, varscan2
- KCNH8 | c.3318T>G p.N1106K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV100111132; called by muse, varscan2
- KCNMA1 | c.2092C>T p.P698S (on ENST00000286628 / NM_001161352.2; = p.L698F on NM_002247.4) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs886043569, COSV54248639, COSV99700047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF21B | c.335T>A p.I112N | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100145205; called by muse, mutect2, varscan2
- KMT2D | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as COSV99986285; called by mutect2, varscan2
- KNG1 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 95/124 reads (77%) | SIFT tolerated (0.14); PolyPhen benign (0.388); catalogued as COSV99405909; called by muse, mutect2, varscan2
- KRT10 | c.771G>T p.R257S | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99510340; called by muse, mutect2, varscan2
- LMX1A | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV99673319; called by muse, mutect2, varscan2
- LRRC10 | c.462C>A p.N154K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100825533; called by muse, mutect2, varscan2
- MAGEB16 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.97); PolyPhen benign (0.02); catalogued as COSV101303340; called by muse, mutect2, varscan2
- MAPK8 | c.495G>C p.L165F | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100827571; called by muse, mutect2, varscan2
- MBL2 | c.329C>G p.S110* | Nonsense Mutation (SNP) | VAF 30/78 reads (38%) | catalogued as COSV100906397; called by muse, mutect2, varscan2
- METTL17 | c.672G>C p.L224F | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.972); catalogued as COSV100228394; called by muse, mutect2, varscan2
- MEX3C | c.1434C>G p.F478L | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV101346348; called by muse, mutect2, varscan2
- MIDN | c.1172A>G p.K391R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99960447; called by muse, mutect2, varscan2
- MIS18BP1 | c.2550A>T p.K850N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100173304; called by muse, mutect2, varscan2
- MUC5AC | c.1369A>G p.S457G | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.04); catalogued as COSV100650725; called by muse, mutect2, varscan2
- MYH13 | c.3705G>T p.M1235I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV99355678; called by muse, mutect2, varscan2
- NCAM2 | c.1199C>A p.A400D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); catalogued as COSV99525585; called by muse, mutect2, varscan2
- NDN | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); catalogued as COSV100086759; called by muse, mutect2, varscan2
- NDST4 | c.1946T>A p.M649K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99996236, COSV99998075; called by muse, mutect2
- NDUFAF5 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV99176252; called by muse, mutect2, varscan2
- NEB | c.3909A>T p.L1303F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV99428518; called by muse, mutect2, varscan2
- NISCH | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 23/38 reads (61%) | catalogued as COSV100617712; called by muse, mutect2, varscan2
- NLGN1 | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.012); catalogued as COSV64322614; called by muse, mutect2, varscan2
- NSDHL | c.33C>A p.D11E | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV100938693; called by muse, mutect2, varscan2
- NUP153 | c.65A>T p.H22L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs749482201, COSV100020901; called by muse, mutect2, varscan2
- OBI1 | c.709A>T p.K237* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV99932650; called by muse, mutect2, varscan2
- OLFM1 | c.1204G>A p.A402T (on ENST00000371793 / NM_001282611.2; = p.A384T on NM_014279.5) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53279064; called by muse, mutect2, varscan2
- OR11H12 | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs1264610703, COSV101612538; called by mutect2, varscan2
- OR5M11 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.902); catalogued as COSV101602070; called by muse, mutect2, varscan2
- OR8G1 | c.707A>T p.K236I | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100422693; called by muse, mutect2, varscan2
- OR8I2 | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100136091; called by muse, mutect2, varscan2
- OR9G1 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV100380588; called by muse, mutect2, varscan2
- OSMR | c.839+1G>A p.X280_splice | Splice Site (SNP) | VAF 26/89 reads (29%) | catalogued as rs779775283, COSV99952494; called by muse, mutect2, varscan2
- OTOF | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99719169; called by muse, mutect2, varscan2
- PABPC1 | c.1556A>G p.N519S | Missense Mutation (SNP) | VAF 67/127 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV59408735; called by muse, mutect2, varscan2
- PCDHA11 | c.630G>T p.L210F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.729); catalogued as COSV100255246; called by muse, mutect2, varscan2
- PDE1C | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100374010; called by muse, mutect2, varscan2
- PIGG | c.844A>T p.T282S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV99574409; called by muse, mutect2, varscan2
- POMZP3 | c.518G>C p.R173T | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.024); catalogued as COSV99300703; called by muse, mutect2, varscan2
- PRDM9 | c.80C>A p.A27D | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.222); catalogued as COSV57010632, COSV99691373; called by muse, mutect2, varscan2
- PRH2 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.471); catalogued as COSV101113354; called by muse, mutect2, varscan2
- PRKCB | c.1942T>A p.F648I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.021); catalogued as COSV100335523; called by muse, mutect2, varscan2
- PSG2 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100283743; called by muse, mutect2, varscan2
- R3HDM4 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.217); catalogued as COSV100846448; called by muse, mutect2
- RBBP6 | c.2206A>G p.R736G | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); catalogued as COSV100155040; called by muse, mutect2, varscan2
- RNF139 | c.683C>A p.T228K | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.42); catalogued as rs35970900, COSV99413757; called by muse, mutect2, varscan2
- ROBO1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as rs781501841, COSV101518082; called by muse, varscan2
- RYR2 | c.3821A>G p.D1274G | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100773166; called by muse, mutect2, varscan2
- RYR2 | c.14411T>C p.M4804T | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs1436352609, COSV100773168; called by muse, mutect2, varscan2
- SCARB2 | c.1399G>T p.G467* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV99358161; called by muse, mutect2, varscan2
- SCGB1C1 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100285355; called by muse, mutect2
- SCN2A | c.73A>G p.I25V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs767145207, COSV99333739; called by muse, mutect2, varscan2
- SF3B2 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 37/123 reads (30%) | catalogued as COSV100360999; called by muse, mutect2, varscan2
- SLCO1C1 | c.1014G>A p.M338I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV99860110; called by muse, mutect2, varscan2
- SPACA7 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.923); catalogued as COSV99366926; called by muse, mutect2, varscan2
- SPNS1 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100209312; called by muse, mutect2, varscan2
- STIP1 | c.856A>G p.I286V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.289); catalogued as rs762737538, COSV100534988; called by muse, mutect2, varscan2
- STYXL2 | c.2048G>A p.S683N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs1459103905, COSV99609966; called by muse, mutect2, varscan2
- TAAR8 | c.784A>C p.T262P | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as COSV99257375; called by muse, mutect2, varscan2
- TASP1 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV100534911; called by muse, mutect2, varscan2
- TDRD3 | c.1838G>T p.W613L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.093); catalogued as COSV52166166; called by muse, mutect2, varscan2
- TET3 | c.1513C>G p.P505A | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1217515956, COSV99996311, COSV99996469, COSV99996643; called by muse, mutect2, varscan2
- THOP1 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100310825; called by muse, mutect2, varscan2
- TLE4 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99513344; called by muse, mutect2, varscan2
- TLR3 | c.1538T>A p.L513Q | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711246; called by muse, mutect2, varscan2
- TOP1MT | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1160670568, COSV100239787; called by muse, mutect2, varscan2
- TPTE | c.795+1G>A p.X265_splice (on ENST00000618007 / NM_199261.4; = p.X247_splice on NM_199259.4) | Splice Site (SNP) | VAF 24/111 reads (22%) | catalogued as rs768791542; called by muse, mutect2, varscan2
- TTN | c.73163G>T p.R24388I (on ENST00000591111; = p.R16964I on NM_003319.4) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | PolyPhen possibly damaging (0.577); catalogued as COSV100632801; called by muse, mutect2, varscan2
- VSX2 | c.629G>A p.W210* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100001785; called by muse, mutect2, varscan2
- ZAN | c.6865A>T p.T2289S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.047); catalogued as COSV100770504; called by muse, mutect2, varscan2
- ZBBX | c.1274G>A p.S425N | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as COSV100285054; called by muse, mutect2
- ZFHX4 | c.1999C>G p.H667D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99268416; called by muse, mutect2, varscan2
- ZMIZ1 | c.1304A>T p.N435I | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as COSV100566612; called by muse, mutect2, varscan2
- ZNF329 | c.772C>G p.P258A | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100798834; called by muse, mutect2, varscan2
- ZNF382 | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV99498146; called by muse, mutect2
- ZNF415 | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV99702104; called by muse, mutect2, varscan2
- ZNF516 | c.2395G>T p.G799C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101487378; called by muse, mutect2, varscan2
- ZNF610 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100017056; called by muse, mutect2, varscan2
- ZNF615 | c.1016C>T p.T339I | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs897793494, COSV100944013; called by muse, mutect2, varscan2
- ZNF85 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.047); catalogued as COSV100059884, COSV100060174; called by muse, mutect2, varscan2
- ZSCAN10 | c.1964C>G p.A655G (on ENST00000252463; = p.A710G on NM_032805.3) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99374341; called by muse, mutect2
- CEACAM8 | c.584_610del p.N195_L203del | In Frame Del (DEL) | VAF 40/222 reads (18%) | called by mutect2, pindel
- COPS8 | c.574_585delinsA p.P192Tfs*13 | Frame Shift Del (DEL) | VAF 16/24 reads (67%) | called by pindel, varscan2*
- DNAH5 | c.12302A>T p.N4101I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IGHV5-51 | c.96G>C p.K32N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IQCN | c.1774dup p.V592Gfs*7 | Frame Shift Ins (INS) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- LRG1 | c.311T>A p.L104Q | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- LRIG3 | c.579_580del p.L194Pfs*19 | Frame Shift Del (DEL) | VAF 45/205 reads (22%) | called by pindel, varscan2
- OVCH1 | c.2111del p.G704Efs*9 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- SLC6A17 | c.1524del p.L509Cfs*48 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | called by mutect2, pindel, varscan2
- TMCO5A | c.565_566del p.E189Sfs*19 | Frame Shift Del (DEL) | VAF 66/254 reads (26%) | called by pindel, varscan2
- ZNF142 | c.232del p.E78Rfs*3 | Frame Shift Del (DEL) | VAF 16/43 reads (37%) | called by pindel, varscan2
- ZNF506 | c.1239_1240dup p.K414Ifs*14 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- ABCB1 | c.2088C>G p.S696= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs775746831, COSV55946914, COSV99714612; called by muse, mutect2, varscan2
- ALPP | c.123C>A p.A41= | Silent (SNP) | VAF 39/78 reads (50%) | catalogued as COSV101235200; called by muse, mutect2, varscan2
- AMOT | c.1308G>A p.Q436= (on ENST00000371959 / NM_001113490.1; = p.Q27= on NM_133265.3) | Silent (SNP) | VAF 85/116 reads (73%) | catalogued as COSV59069567; called by muse, mutect2, varscan2
- APOF | c.561A>T p.P187= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100029167; called by muse, mutect2, varscan2
- CALML5 | c.174C>T p.S58= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs139568157, COSV66702433; called by muse, mutect2, varscan2
- CASS4 | c.909A>G p.K303= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100824960; called by muse, mutect2, varscan2
- CD163 | c.126T>C p.S42= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100776169; called by muse, mutect2, varscan2
- CENPN | c.162T>C p.H54= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99548389; called by muse, mutect2, varscan2
- CTCF | c.1050A>G p.P350= | Silent (SNP) | VAF 86/144 reads (60%) | catalogued as COSV99866707; called by muse, mutect2, varscan2
- CTLA4 | c.297T>C p.D99= | Silent (SNP) | VAF 42/78 reads (54%) | catalogued as COSV99865487; called by muse, mutect2, varscan2
- CTNNA2 | c.1785C>A p.A595= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV100562203, COSV58157772; called by muse, mutect2, varscan2
- CYB561A3 | c.606C>T p.S202= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99582734; called by muse, mutect2, varscan2
- DGCR8 | c.1302C>A p.S434= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV100708191; called by muse, mutect2, varscan2
- DOCK4 | c.3246G>T p.R1082= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV101312847; called by muse, mutect2, varscan2
- ENPP1 | c.1743G>T p.P581= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV100719667; called by muse, mutect2, varscan2
- EPB41L3 | c.2442G>C p.G814= | Silent (SNP) | VAF 67/198 reads (34%) | catalogued as COSV100550476; called by muse, mutect2, varscan2
- FOXD4L3 | c.633G>T p.P211= | Silent (SNP) | VAF 13/32 reads (41%) | called by mutect2, varscan2
- KDM1B | c.2130G>T p.L710= (on ENST00000449850; = p.L477= on NM_153042.4) | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV52810279; called by muse, mutect2, varscan2
- KDM5A | c.231G>A p.L77= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV101239083; called by muse, mutect2, varscan2
- LTBP2 | c.435G>T p.L145= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100001036; called by muse, mutect2
- MAMDC4 | c.699C>T p.H233= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99915933; called by muse, mutect2, varscan2
- MOCOS | c.750G>T p.L250= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as COSV99733977; called by muse, mutect2, varscan2
- MUC16 | c.22138C>A p.R7380= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV101201912, COSV67481398; called by muse, mutect2, varscan2
- MYH1 | c.1776C>T p.N592= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV99877029; called by muse, mutect2, varscan2
- MYO1C | c.603C>T p.Y201= (on ENST00000648651 / NM_001080779.2; = p.Y166= on NM_033375.5) | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs774037863, COSV100704579; called by muse, mutect2, varscan2
- NID1 | c.3435G>A p.K1145= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99938411; called by muse, mutect2, varscan2
- OR6F1 | c.105C>T p.Y35= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV100129492; called by muse, mutect2, varscan2
- PAPOLG | c.1866C>T p.H622= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV99475150; called by muse, mutect2, varscan2
- PDS5B | c.1071G>T p.V357= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as COSV100221584; called by muse, mutect2, varscan2
- PIK3R4 | c.1392G>C p.L464= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100768615; called by muse, mutect2, varscan2
- POLR2A | c.2493C>T p.L831= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs1225787522; called by muse, mutect2, varscan2
- PRDM9 | c.81C>A p.A27= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as COSV99691375; called by muse, mutect2, varscan2
- RAD54L2 | c.639C>T p.H213= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV99621914; called by muse, mutect2, varscan2
- ROBO1 | c.123G>A p.G41= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV101518081; called by muse, varscan2
- RYR2 | c.9999G>A p.V3333= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100773167; called by muse, mutect2, varscan2
- SBK1 | c.774C>T p.G258= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1207450860, COSV100543707; called by muse, mutect2, varscan2
- SIAH3 | c.459G>T p.P153= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV101248077; called by muse, mutect2, varscan2
- SLC16A5 | c.222G>T p.V74= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV100317259; called by muse, mutect2, varscan2
- SLC17A1 | c.1140G>A p.L380= | Silent (SNP) | VAF 30/141 reads (21%) | catalogued as rs368987995; called by muse, mutect2, varscan2
- SLC43A1 | c.579G>C p.V193= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99561260; called by muse, mutect2, varscan2
- SOGA3 | c.1803G>T p.L601= | Silent (SNP) | VAF 45/148 reads (30%) | catalogued as COSV100847089; called by muse, mutect2, varscan2
- SPTB | c.1764C>T p.T588= | Silent (SNP) | VAF 20/176 reads (11%) | catalogued as rs150644201; called by muse, mutect2, varscan2
- SRP72 | c.1146G>A p.L382= | Silent (SNP) | VAF 13/15 reads (87%) | catalogued as COSV100714390; called by muse, mutect2, varscan2
- SYNE1 | c.24621T>C p.H8207= (on ENST00000367255 / NM_182961.4; = p.H8136= on NM_033071.3) | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as rs745333126, COSV99581290; called by muse, mutect2, varscan2
- TIAM2 | c.1638G>A p.T546= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs751294149, COSV59691847; called by muse, varscan2
- TNRC6A | c.1560T>A p.T520= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as COSV100170531; called by muse, mutect2, varscan2
- TOGARAM1 | c.1335G>T p.A445= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as rs748317794, COSV61887452, COSV61888136; called by muse, mutect2, varscan2
- TRAV8-1 | c.291A>G p.K97= | Silent (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- TRHDE | c.2463C>A p.A821= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99672831; called by muse, mutect2, varscan2
- TSPAN8 | c.100C>A p.R34= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99922740; called by muse, mutect2, varscan2
- TTN | c.95175T>A p.V31725= (on ENST00000591111; = p.V24301= on NM_003319.4) | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100632799; called by muse, mutect2, varscan2
- ZNF407 | c.3678G>T p.L1226= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99996922; called by muse, mutect2, varscan2
- ZNF699 | c.1308A>G p.T436= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100427094; called by muse, mutect2, varscan2
- CABP1 | c.655-3745C>A | Intron (SNP) | VAF 14/41 reads (34%) | catalogued as rs767261846, COSV99974902; called by muse, mutect2, varscan2
- CLLU1 | n.854A>C | RNA (SNP) | VAF 12/22 reads (55%) | catalogued as COSV101029272, COSV65903582; called by muse, mutect2, varscan2
- LARP7 | c.1142+82G>A | Intron (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100135362; called by muse, mutect2, varscan2
- MIR518A2 | n.39T>A | RNA (SNP) | VAF 31/120 reads (26%) | called by muse, mutect2, varscan2
- MYL3 | chr3:46832956 T>C | 3'Flank (SNP) | VAF 22/45 reads (49%) | catalogued as COSV101451282; called by muse, mutect2, varscan2
- OR4K13 | c.-1T>C | 5'UTR (SNP) | VAF 6/32 reads (19%) | catalogued as rs371307106; called by muse, mutect2, varscan2
- RARA | c.179-5539C>T | Intron (SNP) | VAF 99/278 reads (36%) | catalogued as rs748984306, COSV99565506; called by muse, mutect2, varscan2
- TPD52L3 | c.*1172A>G | 3'UTR (SNP) | VAF 19/43 reads (44%) | catalogued as rs1408251473, COSV100096192; called by muse, mutect2, varscan2
